Somatic mutation profile of tumor specimen TCGA-B6-A0RU-01A (aliquot TCGA-B6-A0RU-01A-11D-A099-09) from TCGA case TCGA-B6-A0RU, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 40.8 years (14,920 days).
Specimen TCGA-B6-A0RU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46989933-ea5b-41f5-8841-bd8df6f1adc9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0RU-10A (Blood Derived Normal), aliquot TCGA-B6-A0RU-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afcbfcb9-3d57-4462-80f7-ba0405db0541

The open-access MAF lists 49 somatic variants for this specimen: 39 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 29, Silent 10, Nonsense Mutation 6, Frame Shift Del 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 42/104 reads (40%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARHGAP5 | c.882T>A p.S294R | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.709); catalogued as COSV61539915; called by muse, mutect2, varscan2
- ASH2L | c.570G>T p.M190I | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.822); catalogued as COSV51702278; called by muse, mutect2
- BMX | c.1913C>T p.S638L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs756397275, COSV59590978; called by muse, mutect2, varscan2
- CACNA1E | c.1683A>C p.R561S | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV62438642; called by muse, mutect2
- CATSPERE | c.1781A>G p.H594R | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100834869; called by muse, mutect2
- CD248 | c.1870C>T p.Q624* | Nonsense Mutation (SNP) | VAF 14/25 reads (56%) | catalogued as COSV60935648, COSV60938185; called by muse, mutect2, varscan2
- CD3E | c.560A>G p.D187G | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62346827; called by muse, mutect2, varscan2
- CELSR3 | c.2714G>A p.R905H | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs201047576; called by muse, mutect2, varscan2
- CFAP61 | c.2898C>A p.N966K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs1178553406, COSV55650951; called by muse, mutect2, varscan2
- CLEC1A | c.424A>T p.K142* | Nonsense Mutation (SNP) | VAF 12/292 reads (4%) | catalogued as COSV100191082; called by muse, mutect2
- CNBD1 | c.752T>A p.L251Q | Missense Mutation (SNP) | VAF 96/174 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.201); catalogued as COSV72976858; called by muse, mutect2, varscan2
- COG5 | c.1797A>T p.L599F (on ENST00000347053 / NM_001379512.1; = p.L620F on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.075); catalogued as COSV51767321; called by muse, mutect2, varscan2
- COPB2 | c.2491G>T p.E831* | Nonsense Mutation (SNP) | VAF 16/264 reads (6%) | catalogued as COSV100168969, COSV60351557; called by muse, mutect2
- CSNK1E | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs771808437, COSV63292390; called by muse, mutect2, varscan2
- DNAH17 | c.6160T>G p.F2054V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV67762640; called by muse, mutect2
- FABP6 | c.55A>C p.M19L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV67437889; called by muse, mutect2, varscan2
- FAM161B | c.1703A>T p.D568V (on ENST00000651776; = p.D505V on NM_152445.3) | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54105213; called by muse, mutect2
- HLA-DQA2 | c.198G>C p.E66D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV66566938; called by mutect2, varscan2
- ITGA1 | c.1913A>G p.H638R | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as rs368258489; called by muse, mutect2, varscan2
- MORC2 | c.830A>G p.Y277C (on ENST00000397641 / NM_001303256.3; = p.Y215C on NM_014941.3) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53203838; called by muse, mutect2, varscan2
- MTR | c.1961G>C p.G654A | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV63966633; called by muse, mutect2, varscan2
- MUC17 | c.11515C>T p.P3839S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.719); catalogued as COSV60307454; called by muse, mutect2, varscan2
- OR4K17 | c.421T>C p.C141R | Missense Mutation (SNP) | VAF 63/258 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59648704; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.562G>A p.V188I (on ENST00000374531 / NM_001037293.2; = p.V220I on NM_053016.6) | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs777919306, COSV57115218; called by muse, mutect2, varscan2
- PCED1B | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs776179854, COSV71395754; called by mutect2, varscan2
- POLQ | c.7334G>T p.G2445V | Missense Mutation (SNP) | VAF 114/388 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51763658; called by muse, mutect2, varscan2
- RC3H2 | c.1393G>T p.V465L | Missense Mutation (SNP) | VAF 32/403 reads (8%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.785); catalogued as COSV100605280; called by muse, mutect2
- TACC2 | c.7951C>T p.H2651Y (on ENST00000334433; = p.H729Y on NM_006997.4) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs748310126, COSV53291880; called by muse, mutect2, varscan2
- TEX14 | c.1415A>T p.N472I (on ENST00000240361 / NM_001201457.2; = p.N466I on NM_031272.5) | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV53628612; called by muse, mutect2, varscan2
- TTC4 | c.572G>C p.R191T | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs921005206, COSV64885440; called by muse, mutect2
- UNC5D | c.1987C>A p.P663T | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV54844632; called by muse, mutect2, varscan2
- UTRN | c.1711C>T p.R571* | Nonsense Mutation (SNP) | VAF 96/210 reads (46%) | catalogued as rs764291295, COSV100839970, COSV62344578; called by muse, mutect2, varscan2
- ZGRF1 | c.1527T>A p.D509E | Missense Mutation (SNP) | VAF 77/211 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV52203745; called by muse, mutect2, varscan2
- ZNF781 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 98/335 reads (29%) | catalogued as COSV62203269; called by muse, mutect2, varscan2
- HLTF | c.257_259del p.Q86del | In Frame Del (DEL) | VAF 154/506 reads (30%) | called by mutect2, pindel, varscan2
- MED27 | c.270_283del p.L91Sfs*10 | Frame Shift Del (DEL) | VAF 51/232 reads (22%) | called by mutect2, pindel, varscan2
- SLC25A13 | c.1721del p.G574Dfs*22 | Frame Shift Del (DEL) | VAF 42/197 reads (21%) | called by mutect2, pindel, varscan2
- TTI1 | c.1886_1899del p.I629Nfs*35 | Frame Shift Del (DEL) | VAF 23/88 reads (26%) | called by mutect2, pindel, varscan2
- ABCA1 | c.306G>A p.V102= | Silent (SNP) | VAF 71/200 reads (36%) | catalogued as COSV66058472, COSV66060281; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.126C>G p.P42= | Silent (SNP) | VAF 86/364 reads (24%) | catalogued as rs1484185490, COSV57518699; called by muse, mutect2, varscan2
- HIRA | c.1935G>A p.R645= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs775255840, COSV54281199; called by muse, mutect2, varscan2
- PCDHA10 | c.168G>A p.A56= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs782147679, COSV56554916; called by muse, mutect2, varscan2
- RBM42 | c.222G>A p.A74= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV52547148, COSV52550341; called by muse, mutect2, varscan2
- ROBO2 | c.1545C>T p.N515= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV59947342; called by muse, mutect2, varscan2
- SAGE1 | c.289T>C p.L97= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as rs1485259507, COSV61019208; called by muse, mutect2, varscan2
- SLC22A6 | c.39C>T p.V13= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs750880280, COSV64560629; called by muse, mutect2, varscan2
- SPICE1 | c.2397C>A p.V799= | Silent (SNP) | VAF 82/374 reads (22%) | catalogued as COSV55626069; called by muse, mutect2, varscan2
- TSC22D3 | c.82C>T p.L28= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV59779822; called by muse, mutect2, varscan2
